HCMI case HCM-BROD-0448-C15 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Esophagus. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ac371bd7-dd43-4784-8b13-8efb9b7a3474

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1939; Vital status: Dead; Days to death: 307 days; Cause of death: Cancer Related.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C78.2; Tissue or organ of origin: Esophagus, NOS; Site of resection or biopsy: Pleura, NOS; Classification of tumor: metastasis; Age at diagnosis: 78.6 years (28,714 days); AJCC staging edition: 8th; AJCC clinical stage: Stage IVB; AJCC pathologic T: TX; AJCC pathologic N: NX; AJCC pathologic M: M1; AJCC pathologic stage: Stage IVB; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: yes; Prior treatment: No; Esophageal columnar dysplasia degree: Low Grade Dysplasia; Esophageal columnar metaplasia present: Yes; Goblet cells columnar mucosa present: No; Sites of involvement: Liver.
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Chemotherapy, for residual disease; adjuvant Immunotherapy (Including Vaccines), for residual disease; adjuvant Radiation Therapy, NOS, for residual disease; Surgery, NOS, for initial diagnosis; adjuvant Targeted Molecular Therapy, for residual disease.

Follow-up (4 entries)
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Liver; Days to progression: 0 days; Barretts esophagus goblet cells present: No.
- Days to follow up: 195 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Pleura, NOS; Days to progression: 195 days.
- Days to follow up: 307 days; Disease response: Progressive Disease; Progression or recurrence: Yes.
- Follow-up contact recording only the day: day 236.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 70 kg; Height: 170 cm; BMI: 24; Comorbidities: Barrett's Esophagus; Risk factors: Barrett's Esophagus.
- Timepoint category: Prior to Diagnosis; Risk factors: GERD.

Exposures
- Tobacco smoking status: Current Reformed Smoker, Duration Not Specified.

Family history
- Relative with cancer history: yes; Relationship type: First Degree Relative, NOS; Relationship primary diagnosis: Cancer.

Biospecimens (3 samples)
- Sample HCM-BROD-0448-C15-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Pleural Effusion; Preservation method: Frozen.
- Sample HCM-BROD-0448-C15-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Preservation method: Frozen.
- Sample HCM-BROD-0448-C15-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 4.
